Somatic mutation profile of tumor specimen C3L-04495-01 (aliquot CPT0239100012) from CPTAC case C3L-04495, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 36.9 years (13,477 days).
Specimen C3L-04495-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d113a6f-f94e-4027-96d0-1b7039de47a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04495-31 (Blood Derived Normal), aliquot CPT0239150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e400567c-a694-470f-b017-7bfd5dafb5bd

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, RNA 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/531 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 30/616 reads (5%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2
- BCORL1 | c.3449A>C p.K1150T | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54400714, COSV54401194; called by muse, mutect2
- GBA | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 32/875 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285705042; called by muse, mutect2
- MARK2 | c.1334G>A p.R445Q (on ENST00000402010 / NM_001039469.2; = p.R444Q on NM_004954.5) | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1309620304; called by muse, mutect2
- NAV3 | c.4580G>C p.R1527T | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57062931; called by muse, mutect2
- OR8J3 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs146502389; called by muse, mutect2
- THOP1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1227793404; called by muse, mutect2
- CASK | c.1576A>T p.R526W | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPC2 | c.1600A>G p.N534D | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- FTO | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 26/672 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); called by muse, mutect2
- KCNE5 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2
- MYH4 | c.2450G>A p.C817Y | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2
- PPP4R3C | c.1798A>C p.N600H | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN8A | c.1259C>A p.A420E | Missense Mutation (SNP) | VAF 24/519 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- SUPT20HL1 | c.285A>C p.E95D | Missense Mutation (SNP) | VAF 15/561 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2
- AGFG1 | c.1260A>G p.S420= | Silent (SNP) | VAF 32/473 reads (7%) | catalogued as rs373953198; called by muse, mutect2
- GABRA1 | c.636A>G p.G212= | Silent (SNP) | VAF 24/627 reads (4%) | called by muse, mutect2
- MRC1 | c.105C>T p.C35= | Silent (SNP) | VAF 27/892 reads (3%) | catalogued as rs1407613157; called by muse, mutect2
- RBM43 | c.627A>G p.L209= | Silent (SNP) | VAF 19/238 reads (8%) | called by muse, mutect2
- CTSH | c.405+78A>G | Intron (SNP) | VAF 34/596 reads (6%) | called by muse, mutect2
- DCHS2 | n.7287T>A | RNA (SNP) | VAF 26/360 reads (7%) | called by muse, mutect2
- OR52B1P | n.210G>A | RNA (SNP) | VAF 27/405 reads (7%) | catalogued as rs1213710951; called by muse, mutect2
- RDX | c.13-348G>T | Intron (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
